HCMI case HCM-CSHL-0868-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c439d71-50e3-48d2-82a6-4ff0b4ce284a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive.

Diagnoses (2)
1. Serous surface papillary carcinoma (the primary disease): ICD-O-3 morphology code: 8461/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,759 days); AJCC staging edition: 8th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage IIIB; Tumor grade: High Grade; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Residual disease: R0; Ovarian specimen status: Ovarian Capsule Intact; Ovarian surface involvement: Present; Sites of involvement: Liver / Omentum / Abdomen / Uterus / Other / Mesentery.
   Pathology details: Largest extrapelvic peritoneal focus: Macroscopic (2cm or less); Lymph nodes positive: 0; Lymph nodes tested: 13; Tumor largest dimension diameter: 0.6 cm.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 16 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 20 days; Days to treatment end: 60 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 94 days.
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: metastasis; Age at diagnosis: 62.3 years (22,759 days); Sites of involvement: Uterus / Omentum / Abdomen / Other / Mesentery.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 13.

Follow-up (5 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days; Procedures performed: Colonoscopy.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 0 days.
- Days to follow up: 466 days (1.3 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contacts recording only the day: day 16, day 382.

Molecular and laboratory tests
- BRCA1 mutation, nos (Targeted Sequencing): Negative.
- BRCA2 mutation, nos (Targeted Sequencing): Negative.
- CA-125: 12.
- CA-125: 30.
- CA-125: 80.
- CA-125: 877.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- TP53 (IHC): Normal.

Other clinical attributes
- Day 0: Risk factors: Endometriosis.
- Timepoint category: Initial Diagnosis; Weight: 49.9 kg; Height: 165.1 cm; BMI: 18.
- Timepoint category: Prior to Diagnosis; Risk factors: Endometriosis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0868-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0868-C56-06A-01-S1-HE: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 50; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0868-C56-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 71; Percent normal cells: 12; Percent necrosis: 10; Percent stromal cells: 38; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0868-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0868-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
